Gene-level copy-number profile of tumor specimen HTMCP-03-06-02148-01A from CGCI case HTMCP-03-06-02148, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 44.9 years (16,382 days).
Specimen HTMCP-03-06-02148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4205cfe8-1a8d-402b-8bcd-6f0d7fcecd90.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02148-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,254 have no estimate.
https://portal.gdc.cancer.gov/files/6583a199-7de4-48ac-8540-7d6446c583fa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 25; copy number 2: 6,670; copy number 3: 26,494; copy number 4: 18,443; copy number 5: 4,871; copy number 6: 8; copy number 7: 1,805; copy number 8: 4; copy number 9: 13; copy number 13: 1; copy number 53: 17; copy number 64: 6.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,846 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 7–13 (broad region; genes not listed).
- chr8:145,047,860–145,066,685, 2 genes, copy number 8: AC139103.1, C8orf33.
- chr18:3,247,481–8,546,817, 89 genes, copy number 7–64 (broad region; genes not listed).
- chr22:50,756,948–50,801,309, 2 genes, copy number 8: RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
